Somatic mutation profile of tumor specimen TCGA-VD-AA8M-01A (aliquot TCGA-VD-AA8M-01A-11D-A39W-08) from TCGA case TCGA-VD-AA8M, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIA; Age at diagnosis: 64.4 years (23,507 days).
Specimen TCGA-VD-AA8M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b911cdb5-3bb7-4d77-9315-51336b716666.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-AA8M-10A (Blood Derived Normal), aliquot TCGA-VD-AA8M-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f40932ec-81e1-45fe-bbdf-4f3dc8deef3d

The open-access MAF lists 22 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 46/96 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CARMIL1 | c.1345G>C p.A449P | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100278809; called by muse, mutect2, varscan2
- KAT6A | c.5464A>G p.N1822D | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as rs769858065; called by muse, mutect2, varscan2
- KRT83 | c.847A>G p.I283V | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.255); catalogued as rs942790024; called by muse, mutect2, varscan2
- LAMA1 | c.4415A>G p.H1472R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as rs1233781191; called by muse, mutect2
- MUC16 | c.40739A>G p.E13580G | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.946); catalogued as rs1310600107; called by muse, mutect2, varscan2
- RECQL5 | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs766805103, COSV58639425; called by muse, mutect2, varscan2
- ZNF680 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs1472467735, COSV59016994; called by muse, mutect2
- HMGXB4 | c.1091C>A p.P364H | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.241); called by muse, varscan2
- NREP | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- OGN | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PDIA5 | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- PPP1R12C | c.2300A>G p.K767R | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC40A1 | c.1196A>G p.D399G | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- STIP1 | c.1579A>G p.I527V | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TGM4 | c.1861A>C p.K621Q | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- WDR41 | c.17T>G p.I6S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ZBTB8A | c.243C>G p.D81E | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF658 | c.1895G>A p.C632Y | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPR1 | c.1644C>T p.G548= | Silent (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- SHPK | c.1228C>T p.L410= | Silent (SNP) | VAF 40/75 reads (53%) | called by muse, mutect2, varscan2
- SNORD116-11 | n.50T>G | RNA (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
